Somatic mutation profile of tumor specimen TARGET-20-PARUSN-09A (aliquot TARGET-20-PARUSN-09A-01D) from TARGET case TARGET-20-PARUSN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.4 years (3,816 days).
Specimen TARGET-20-PARUSN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d472c23c-7155-4445-9e59-516bc4cf06b3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARUSN-14A (Bone Marrow Normal), aliquot TARGET-20-PARUSN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f082ae68-6423-44fb-824e-c0c1546e9f96

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 48/302 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 38/300 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CPNE6 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs1356633648, COSV53742732; called by muse, mutect2, varscan2
- TRO | c.4189G>A p.G1397S | Missense Mutation (SNP) | VAF 9/270 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as rs1263944061, COSV51499921; called by muse, mutect2
